Gene-level copy-number profile of tumor specimen ALCH-B2SA-TTR1-A from ALCHEMIST case ALCH-B2SA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.0 years (22,272 days).
Specimen ALCH-B2SA-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 19137d0d-4dbf-48d4-864e-a9ef31b91961.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2SA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/4838ae1d-bd41-41af-aacc-b2281dafa6ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 3,158; copy number 2: 26,282; copy number 3: 21,130; copy number 4: 6,459; copy number 5: 1,054; copy number 6: 173; copy number 7: 87; copy number 9: 1; copy number 15: 33; copy number 18: 1; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,777,595–52,792,068, 1 gene: ITIH1.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–1): RN7SL5P.
- chr14:103,121,476–103,141,959, 2 genes (within-gene range 0–2): TNFAIP2, NDUFB4P11.
- chr15:25,180,497–25,185,712, 4 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9.
- chr21:44,200,602–44,244,993, 4 genes: AP001057.1, ICOSLG, AP001059.2, AP001059.1.
- chr21:44,250,813–44,251,520, 1 gene (within-gene range 0–1): DNMT3L-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,350 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,171,609–206,504,456, 949 genes, copy number 5 (broad region; genes not listed).
- chr3:96,244,732–96,619,831, 7 genes, copy number 6: AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8.
- chr3:160,225,496–172,711,218, 160 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:172,711,151–172,725,038, 1 gene, copy number 6: AC108667.2.
- chr3:173,396,284–174,286,644, 1 gene, copy number 5 (within-gene range 4–5): NLGN1.
- chr3:173,910,498–174,057,864, 2 genes, copy number 5: NLGN1-AS1, RN7SKP234.
- chr14:33,924,227–40,390,547, 121 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr18:21,825,487–21,831,539, 3 genes, copy number 5 (within-gene range 3–5): MIR133A1HG, MIR133A1, MIR1-2.
- chr18:21,871,446–23,026,488, 26 genes, copy number 5: AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr20:5,292,388–10,636,829, 77 genes, copy number 6–15 (within-gene range 3–15) (broad region; genes not listed).
- chr21:44,107,373–44,210,114, 3 genes, copy number 9–24 (within-gene range 0–24): PWP2, GATD3A, LINC01678.

Autosomal genes at a single copy (total copy number 1): 2,361. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
